Somatic mutation profile of tumor specimen TARGET-40-PASEBY-01A (aliquot TARGET-40-PASEBY-01A-01D) from TARGET case TARGET-40-PASEBY, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.6 years (4,249 days).
Specimen TARGET-40-PASEBY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2444ef4e-ab50-4a71-93ee-1c782093eed1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PASEBY-10A (Blood Derived Normal), aliquot TARGET-40-PASEBY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f640b88-f80d-4d3a-ba5a-e3e358626ec0

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 3, Splice Region 2, Splice Site 2, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA2A | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV99701897; called by muse, mutect2
- C10orf71 | c.3562G>A p.A1188T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60510534; called by muse, mutect2, varscan2
- KDM3B | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs761718608; called by muse, mutect2, varscan2
- OR5B12 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100222406, COSV56905096; called by muse, mutect2, varscan2
- PTPRO | c.1229G>A p.R410Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.414); catalogued as rs1344922746, COSV55504003; called by muse, mutect2, varscan2
- SYT10 | c.1199-1G>T p.X400_splice | Splice Site (SNP) | VAF 31/85 reads (36%) | catalogued as rs866928548; called by muse, mutect2, varscan2
- TRIM51EP | n.743G>A | Splice Region (SNP) | VAF 19/93 reads (20%) | catalogued as rs1336140155; called by muse, mutect2, varscan2
- BPTF | c.3360G>C p.K1120N | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CNTNAP5 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MSL2 | c.1692T>G p.D564E | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- RSU1P1 | n.322T>C | Splice Region (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2
- SLITRK3 | c.490A>C p.I164L | Missense Mutation (SNP) | VAF 38/57 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- SV2C | c.1086A>C p.L362F | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- TRAV10 | c.53-1G>C p.X18_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- TRAV16 | c.127A>T p.N43Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XKR9 | c.743A>G p.K248R | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- B4GALNT3 | c.1974C>T p.N658= | Silent (SNP) | VAF 63/180 reads (35%) | called by muse, mutect2, varscan2
- MLXIP | c.2592G>A p.A864= | Silent (SNP) | VAF 19/209 reads (9%) | catalogued as rs561027162, COSV100038613; called by muse, mutect2
- MTMR11 | c.1740C>T p.D580= (on ENST00000439741 / NM_001145862.2; = p.D508= on NM_181873.3) | Silent (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
- SMARCA4 | c.4068G>A p.R1356= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100758136; called by muse, mutect2
- CHEK2P5 | n.71A>C | RNA (SNP) | VAF 68/178 reads (38%) | called by muse, mutect2, varscan2
- DYRK1A | c.1099-15T>C | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- RSU1 | c.-33C>G | 5'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- SPG7 | c.1429-113A>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs1412755657; called by muse, mutect2
- TTN | c.10360+5225T>C | Intron (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
